CCDI case PBCPIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b9eb7a2f-f130-4c24-99b9-b2b6b461a0e6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.5 years (924 days).

Biospecimens (2 samples)
- Sample 0DX4EQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
